Surgical pathology report (de-identified scan), TCGA case TCGA-97-8179, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-8179-01A (Primary Tumor).

[page 1 of 12]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE: [REDACTED]

SPECIMENS:

1. F/S LUNG, RIGHT UPPER LOBE NODULE
2. DEEPER MARGIN POSTERIOR SEGMENT RIGHT UPPER LOBE
3. STATION 11 LYMPH NODE, RIGHT
4. LUNG, RIGHT UPPER LOBE
5. STATION 4 LYMPH NODE, RIGHT
6. LEVEL 9 LYMPH NODE, RIGHT
7. STATION 7 LYMPH NODE, RIGHT
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

Reason For Addendum #3: Molecular Studies

Reason For Addendum #4: Molecular Studies

DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE: WEDGE RESECTION

- **ADENOCARCINOMA, ACINAR PREDOMINANT (1.2 CM), SEE NOTE.**
- **THE STAPLE LINE MARGIN IS FREE OF TUMOR.**

Note: The tumor consists of acinar (60%) and lepidic (40%) components. Results of mutational studies will be reported in addenda.

2. LUNG, RIGHT UPPER LOBE, POSTERIOR SEGMENT, DEEPER MARGIN: WEDGE

RESECTION:

- **FIBROELASTOTIC SCAR, CONSISTENT WITH APICAL CAP.**
- **NO TUMOR OR GRANULOMAS ARE SEEN.**

3. LYMPH NODE, RIGHT LEVEL 11: BIOPSY

- **FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/4).**

4. LUNG, RIGHT UPPER LOBE: COMPLETION LOBECTOMY

[page 2 of 12]
- NO RESIDUAL TUMOR IS SEEN.
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

5. LYMPH NODE, RIGHT LEVEL 4: BIOPSY

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

6. LYMPH NODE, RIGHT LEVEL 9: BIOPSY

- BENIGN ALVEOLAR PARENCHYMA.
- NO LYMPHOID TISSUE, TUMOR OR GRANULOMAS ARE SEEN.

7. LYMPH NODE, RIGHT LEVEL 7: BIOPSY

- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

Specimens: 1: F/S LUNG, RIGHT UPPER LOBE NODULE

2: DEEPER MARGIN POSTERIOR SEGMENT RIGHT UPPER LOBE

3: STATION 11 LYMPH NODE, RIGHT

4: LUNG, RIGHT UPPER LOBE

5: STATION 4 LYMPH NODE, RIGHT

6: LEVEL 9 LYMPH NODE, RIGHT

7: STATION 7 LYMPH NODE, RIGHT

LUNG: Resection

SPECIMEN

Specimen: Lung

Procedure: Lobectomy

Specimen Laterality: Right

Tumor Site: Upper lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

1.2cm

Visceral Pleura Invasion: Not identified

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by invasive carcinoma

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

LYMPH NODES

Extranodal Extension: Not identified

STAGE (pTNM)

[page 3 of 12]
Primary Tumor (pT):

pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (i.e., not in the main bronchus); or Superficial spreading tumor of any size with its invasive component limited to the bronchial wall, which may extend proximally to the main bronchus

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number Examined

9

Number Involved

0

ADDITIONAL NON-TUMOR

Additional Pathologic Finding(s): Emphysema

[REDACTED]

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

[REDACTED] ex-smoker (60 pack-years) with a 1.3 cm RUL solid nodule and multiple bilateral ground-glass nodules.

MACROSCOPIC DESCRIPTION:

The specimen is received in seven parts, each labeled with the patient's name.

1. Part one is received fresh, labeled 'right upper lobe nodule'.

It consists of a pre-cut wedge biopsy of the lung measuring 7.5 x 2 x 1.6 cm. The staple line measures 7.8 cm, and is shaved. The parenchyma around it is inked in black. Also noted, is a second piece of tissue, which contains part of the nodule, measuring 1 x 1 x 0.3 cm. At the pre-cut opened area, there is a grey-pink nodule measuring 1 x 0.9 cm. This mass is located 0.4 cm from the staple line margin. Frozen section is performed on the nodule and re-submitted for permanent section. Representative sections are submitted.

2. Part two is received fresh, labeled 'deeper margin posterior segment right upper lobe'. It consists of a pre cut wedge biopsy of the lung, measuring 8.5 x 4 x 3 cm. The staple line measures 9 cm which is shaved and the parenchyma around the staple line is inked in black. At the pre cut area the pleura is gray pink thickened and with a bleb. Beneath the thickened pleura the parenchyma is dark red firm and no nodule is grossly identified. Representative sections

[page 4 of 12]
are submitted.

3. Part three is received in saline, labeled 'station #11, lymph node'. It consists of four pieces of tan brown soft tissue, ranging in size from 0.5 cm to 1.2 cm in greatest dimension. The specimen is entirely submitted.

4. Part four is received fresh, labeled 'right upper lobe'. It consists of a 168 gram lobectomy, measuring 14 x 7 x 2 cm. The bronchial margin measures 2 cm in length. There is also a staple line spanning the length of the specimen. The bronchial and vascular margin are shaved and submitted entirely. The pleural surface has a tan purple appearance with multiple black streaks. No palpable masses are grossly identified. The staple line is inked blue and shaved and representative section is submitted. The specimen is serially sectioned revealing a homogenous tan red cut surface. No gross nodules are identified. Representative sections are submitted.

5. Part five is received in saline, labeled 'station #4 lymph node'. It consists of multiple pieces of fibrofatty tissue, ranging in size from 0.6 cm to 1 cm in greatest dimension. The specimen is entirely submitted in one cassette.

6. Part six is received in saline, labeled 'level #9 lymph node'. It consists of one piece of tan soft tissue measuring 0.7 x 0.3 x 0.3 cm. The specimen is entirely submitted in one cassette.

7. Part seven is received in saline, labeled 'station #7 lymph node'. It consists of four pieces of tan soft tissue, ranging in size from 0.4 cm to 0.6 cm in greatest dimension. The specimen is entirely submitted in one cassette.

SUMMARY OF SECTIONS:

- 1A frozen section, remainder of the nodule
- 1B-1D remainder of the nodular area
- 1E adjacent section to the nodule
- 1F staple line margin
- 2A-2C thickened pleura and underlying parenchyma
- 2D bleb area
- 2E staple line margin
- 3A entirely submitted
- 4A vascular and bronchial margin, shaved
- 4B parenchymal margin

[page 5 of 12]
4C-4F representative section of lung
5A entirely submitted
6A entirely submitted
7A entirely submitted

SPECIAL PROCEDURES:

INTRA - OPERATIVE CONSULTATION:

1. Lung, right upper lobe nodule; frozen section

Adenocarcinoma. Results reported by [REDACTED]

[REDACTED] and repeat-back provided by [REDACTED]

Intra-Operative Consultation #1 performed by [REDACTED]

Final Diagnosis performed by [REDACTED]

[REDACTED] signed [REDACTED]

ADDENDUM #1 FOR MOLECULAR TESTS:

KRAS, EGFR and ALK FISH were sent on [REDACTED] for patient,. The test is to be performed on tissue from case

[REDACTED] The case report, slides, and blocks for the cited accession number were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected block 1D appropriate to the specifications of the ordered molecular analysis. x1 H&E and x9 unstained slides were prepared and forwarded to [REDACTED] where the subject molecular test will be performed. An addendum report will be issued when the results of this molecular test are available.

[page 6 of 12]
Addendum #1 performed by

Electronically signed

MOLECULAR ONCOLOGY
KRAS MUTATION ANALYSIS

Clinical Data: Adenocarcinoma

RESULTS: Wild type gene.

INTERPRETATION: No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with poor prognosis, and resistance to targeted tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer (NSCLC). KRAS mutations occur in 15-30% of NSCLC patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected. This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

Analysis of EGFR mutation or gene amplification status may provide additional information regarding this patient's probability of response to targeted tyrosine kinase inhibitor therapies, if

[page 7 of 12]
clinically indicated. See references.

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

[REDACTED]

This test was developed and its performance characteristics determined by [REDACTED]. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be only used in the context of other diagnostic tests or clinical work-up related to treatment decisions. [REDACTED] is a business unit of [REDACTED], a wholly-owned subsidiary of [REDACTED].

Electronically signed by: [REDACTED]

Date: [REDACTED]

[REDACTED]

Addendum #2 performed by

[REDACTED]

[page 8 of 12]
ADDENDUM #3:

[REDACTED]

EGFR Mutation Analysis

[REDACTED]

Referring Physician: [REDACTED]

Body Site: Right upper lobe of lung

Clinical Data: Adenocarcinoma

RESULTS: No mutation detected.

INTERPRETATION: No mutations were identified in the sample provided for analysis. Fewer than 5% of non-small cell lung carcinoma patients without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 30% tumor cellularity upon pathologist review.

A frequently occurring sequence change 2361G>A (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

[page 9 of 12]
This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the samples, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

[REDACTED]

DISCLAIMER:

The test was developed and its performance characteristics determined by [REDACTED]. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

Electronically signed by: [REDACTED]
Date: [REDACTED]

[REDACTED]

[page 10 of 12]
Addendum #3 performed by

ADDENDUM #4:

Fluorescence In-Situ Hybridization (FISH)

Specimen [REDACTED] MD

Body Site: Right upper lobe of lung

Specimen Type: Slides

Clinical Data: Adenocarcinoma

INTERPRETATION:

Negative for a rearrangement involving the ALK gene.

Probe #Nuclei Examined % Positive Nuclei %

Control values

2p23(ALK) 100 0 <15.0

A total of 100 cells were scored.

FINDINGS:

FISH was performed on paraffin embedded tissue sections using the Vysis ALK Break Apart Probe for the ALK gene at 2p23 [REDACTED]

[REDACTED] When a rearrangement involving ALK is present, either inversion or translocation, one of the two fusion signals separates as one red and one green signal. In this specimen, separated signals were present in 0% of the nuclei scored. This result is within the normal limits.

COMMENTS: Three to four copies of ALK were observed in 59.0% of cells. This gain of intact ALK fusion hybridization signals represents an aneuploid population with extra copies of chromosome 2/2p ALK region. Additional copies of ALK are not uncommon in NSCLCs, although the significance of extra copies of the ALK gene in lung carcinoma is unclear at this time [REDACTED]

[page 11 of 12]
[REDACTED]

ISCN RESULTS: nuc ish(ALKx3 4)[59/100]

[REDACTED]

The Vysis ALK Break Apart Probe FISH test [REDACTED] is FDA approved for use in the detection of rearrangements involving the ALK gene via fluorescence in situ hybridization (FISH) in formalin-fixed paraffin-embedded (FFPE) non-small cell lung cancer (NSCLC) tissue specimens.

[REDACTED]

Addendum #4 performed by

[REDACTED]
Electronically signed [REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

[page 12 of 12]
This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED] Department of Pathology.

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 09cbfe96-3755-4da5-8977-ab3df89d8f0c (TCGA-97-8179.8ED138EF-C9FE-45DD-870A-A438F6F22214.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).